Gene-level copy-number profile of tumor specimen TCGA-CN-5359-01A from TCGA case TCGA-CN-5359, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.8 years (21,858 days).
Specimen TCGA-CN-5359-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.57ac2765-46e2-47cd-9cf8-a0d31b5609d3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-5359-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9b04f3d9-5842-4a92-a41b-22985eca79fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 938; copy number 2: 20,139; copy number 3: 17,043; copy number 4: 16,226; copy number 5: 3,226; copy number 6: 1,301; copy number 7: 593; copy number 8: 90; copy number 9: 197; copy number 10: 24; copy number 11: 7; copy number 12: 4; copy number 14: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-5359-01A-01D-1432-01): tumor purity 0.19, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,466 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,992,834–96,022,890, 35 genes, copy number 5 (within-gene range 3–5): ABCA4, AC093579.1, ARHGAP29, RN7SL440P, ARHGAP29-AS1, GAPDHP29, AC097059.1, AC118469.1, AC118469.2, ABCD3, F3, AC093117.1, SLC44A3-AS1, KATNBL1P2, MIR378G, SLC44A3, CNN3, AC105942.1, ALG14, ALG14-AS1, TLCD4, TLCD4-RWDD3, AC092802.3, Y_RNA, AC092802.1, RWDD3, AC092802.2, AC092802.4, LINC01760, LINC01650, AL445218.1, LINC01761, LINC02607, AL683887.1, LINC02790.
- chr1:175,877,343–188,242,678, 221 genes, copy number 5 (broad region; genes not listed).
- chr2:162,768,936–164,843,679, 12 genes, copy number 7–11: KCNH7-AS1, RPL7P61, RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F.
- chr2:164,858,432–164,955,525, 3 genes, copy number 7: RNA5SP110, RNA5SP111, SLC38A11.
- chr2:171,517,270–176,242,993, 98 genes, copy number 5–12 (broad region; genes not listed).
- chr2:176,929,985–177,559,299, 22 genes, copy number 8: RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B.
- chr3:122,325,248–198,222,513, 1,390 genes, copy number 5–7 (broad region; genes not listed).
- chr4:48,986,275–85,246,912, 558 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–68,293,818, 335 genes, copy number 5–6 (broad region; genes not listed).
- chr8:71,675,300–74,099,853, 53 genes, copy number 6: AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P.
- chr8:74,103,516–74,106,744, 1 gene, copy number 6: AC087672.1.
- chr8:93,719,574–133,134,903, 570 genes, copy number 5–6 (broad region; genes not listed).
- chr9:6,413,151–10,612,723, 35 genes, copy number 5–8 (within-gene range 3–8): UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1, PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1.
- chr10:32,958,437–48,672,424, 291 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr10:49,014,236–53,766,614, 68 genes, copy number 8–14 (within-gene range 1–14) (broad region; genes not listed).
- chr10:54,452,423–54,656,051, 4 genes, copy number 8: RNU6-687P, AL353784.1, NEFMP1, MIR548F1.
- chr12:66,767–34,249,958, 850 genes, copy number 5–6 (broad region; genes not listed).
- chr13:104,814,327–114,337,626, 162 genes, copy number 5 (broad region; genes not listed).
- chr14:21,990,496–22,506,702, 72 genes, copy number 5 (broad region; genes not listed).
- chr16:87,595,131–90,222,851, 110 genes, copy number 6 (broad region; genes not listed).
- chr17:9,547,298–10,259,232, 17 genes, copy number 6: AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN, GAS7, RPS27AP1.
- chr20:87,250–24,446,314, 487 genes, copy number 5 (broad region; genes not listed).
- chr20:24,491,472–24,502,345, 1 gene, copy number 5: AL157413.1.
- chr22:15,290,718–16,934,003, 71 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
